Surgical pathology report (de-identified scan), TCGA case TCGA-FR-A728, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of North Carolina, specimen TCGA-FR-A728-01A (Primary Tumor).

[page 1 of 3]
DERMATOPATHOLOGY

Case Number :

HD-6.3

Melanoma, superficial
spreading 8/43/13
Skin y shoulder C44,
JW 8/11/13

Diagnosis:

A: Left shoulder, excision

Histologic type: Biopsy site changes and residual superficial spreading melanoma

Breslow depth: 12 mm

Ulceration: EXTENSIVELY PRESENT

Consumption of the epidermis: present

Margins: all margins are widely free

Clark level: IV

Vertical growth phase: present

Mitoses: 6.2 per square mm

Tumor infiltrating lymphocytes: present, non-brisk

Regression: not identified

Lymphovascular space invasion: PRESENT

Satellite nodule: not identified

Perineural invasion: not identified

Coexisting nevus: present

Pigmentation: present, mild

Solar elastosis: present, mild

AJCC Staging

pT4b pNx pMx

This staging information is based on this pathologic specimen and may be incomplete. A comprehensive review of all available information is recommended to determine final staging.

B: Sentinel lymph node, left axillary #1, removal

-Metastatic melanoma involving 1 out of 1 sentinel lymph nodes as a few immunohistochemically-positive tumor cells and no evidence of capsular involvement or extracapsular extension (1/1)

C: Sentinel lymph node, left axillary #2, removal

-No evidence of melanoma in 1 sentinel lymph node (0/1)
-Immunostains and levels are negative in all five blocks

D: Sentinel lymph node, left axillary #3, removal

-Metastatic melanoma involving 1 out of 1 sentinel lymph nodes, with the largest diameter measuring approximately 7 mm and focal capsular involvement but no extracapsular extension (1/1)

-Metastatic melanoma is seen in the H & E sections and immunostains

-Block D1 will be sent for BRAF testing

[page 2 of 3]
E: Additional superior margin, excision
-No evidence of melanoma

F: Additional lateral margin, excision
-No evidence of melanoma

Clinical History:
-year-old woman with melanoma

Gross Description:

A: The specimen bears a long suture indicating lateral and a short suture indicating superior and measures 6.8 x 6 x 2.5 cm. Viewing the specimen with the short suture at the 12:00 position and the long suture at the 3:00 position, the margin encompassing the 12:00-3:00 quadrant is inked green, 3:00-6:00 quadrant is inked yellow, 6:00-9:00 quadrant is inked black, and the 9:00-12:00 quadrant is inked orange. Sections are submitted as per the block summary.

Block Summary:

A1-A12: Radial perpendicular sections from biopsy site to corresponding clock number margin (ie. A1 = 1:00 margin, A2 = 2:00 margin)

A13-A22: Entire biopsy site/lesion

B: The fibrofatty specimen was received labeled with the patient's name and measured 24 x 14 x 12 mm. The tissue is serially sectioned at very thin intervals and entirely submitted as B1-B5,

C: The fibrofatty specimen was received labeled with the patient's name and measured 20 x 20 x 20 mm. The tissue is serially sectioned at very thin intervals and entirely submitted as C1-C5,

D: The fibrofatty specimen was received labeled with the patient's name and measured 35 x 25 x 18 mm. The tissue is serially sectioned at very thin intervals and entirely submitted as D1-D5,

E: The triangular-shaped specimen was received labeled with the patient's name and measured 22 x 10 x 6 mm. The specimen is inked green, serially sectioned, and entirely submitted as E1-E2,

[page 3 of 3]
F: The triangular-shaped specimen was received labeled with the patient's name and two tissues measuring 20 x 20 x 10 mm and 18 x 15 x 12 mm. The specimen is inked green, serially sectioned, and entirely submitted as F1-F3,

Light Microscopy:

Light microscopic examination is performed by Dr. S100 protein and Melan A immunostains were performed on blocks B1, C1, and D1; tyrosinase and HMB-45 were performed on blocks B2, C2, and D2; Sox10 and MiTF were performed on blocks B3, C3, and D3; KBA.62 and PNL2 were performed on blocks B4, C4, and D4; and p75/NGFR was performed on blocks B5, C5, and D5. All are utilized to evaluate for metastatic melanoma.

Histology Discrepancy		✓

Source: NCI Genomic Data Commons file f79136a3-2dde-4753-a3b1-11aaacd1de69 (TCGA-FR-A728.F3C14D17-8681-4925-BDC5-CFE56F68342E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).